Surgical pathology report (de-identified scan), TCGA case TCGA-PJ-A5Z8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Gundersen Lutheran, specimen TCGA-PJ-A5Z8-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: F

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

SPECIMEN

Right partial nephrectomy

TUMOR

Histologic type: Papillary renal carcinoma, solid variant

Histologic grade (Fuhrman nuclear grade): Grade 3

Focality: Solitary within specimen

Tumor size (greatest dimension): 2.5cm

Extent of direct tumor invasion: No direct extension beyond kidney

Sarcomatoid component: Absent

Lymphovascular invasion (excluding renal vein): Absent

Renal vein involvement: Indeterminate

Cannot be assessed

Pathologic findings in non-neoplastic kidney:

No additional significant pathologic findings

Adrenal: Not present

Comment: By convention, this is consistent with "Type 2" papillary renal carcinoma.

MARGINS

All margins negative for carcinoma

LYMPH NODES

Cannot be assessed

STAGING (AJCC)

Primary Tumor: pT1a

Lymph Nodes: pNX

Distant Metastasis: Not applicable

CLINICAL INFORMATION:

Right renal mass;

specimen.

SPECIMEN(S) RECEIVED:

Right renal mass

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS C64.9
JW 4/29/13

[page 2 of 2]
Patient: [REDACTED]

MRN: [REDACTED]

GROSS DESCRIPTION:

Received fresh is a 4 gram, 2.9 x 2.4 x 2.3 cm resection of rubbery to soft, nodular red-yellow renal tissue. There is some adherent blood clot present at the irregular, partially cauterized margin of resection. This margin is inked black. Sectioning reveals that nearly the entire specimen is replaced by 2.5 x 2 x 1.8 cm yellow-gray mass which grossly comes to within 0.1 cm of the inked parenchymal margin of resection. There is a narrow rim of normal-appearing renal parenchyma present at the periphery of the mass. Representative sections are submitted in A1 - A3.

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed

Pathology Report

Source: NCI Genomic Data Commons file 56f3f8e7-2ada-481d-8acd-65a4832118fd (TCGA-PJ-A5Z8.A9D35DC2-1E48-4ED8-885A-7C2293066AE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).